Surgical pathology report (de-identified scan), TCGA case TCGA-91-6848, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site ABS - IUPUI, specimen TCGA-91-6848-01A (Primary Tumor).

[page 1 of 4]
Final Pathologic Diagnosis:

- A. Anterior lymph node, excision:
Metastatic carcinoma, non-small cell.
Small sclerotic granulomata.
- B. Inferior ligament lymph nodes, excision:
No evidence of metastatic carcinoma.
Multiple small sclerotic granulomata.
- C. Hilar lymph node, excision:
Metastatic carcinoma, non-small cell.
Extranodal extension of tumor, present.
- D. Lymph nodes, five, excision:
No evidence of metastatic carcinoma.
- E. Left lung, upper lobe, left upper lobectomy:
Non-small cell carcinoma, moderate to poorly differentiated.
Maximal diameter of tumor 10.2 cm.
Bronchial margin, free of tumor.
Frozen section diagnosis FSE1, confirmed.
Chest wall margin, soft tissues, resection margin, free of tumor.
Frozen section diagnosis FSE2, confirmed.
Ribs and soft tissue, pending decalcification.
Vascular margin, free of tumor.
Peripheral margins of resection, free of tumor.
Extensive tumor necrosis.
Lymph nodes, three, no evidence of metastatic carcinoma.
Moderate to marked sinus histiocytosis and anthracosis.
- F. Subcarinal lymph node, excision:
No evidence of metastatic carcinoma.
- G. Lymph nodes, AP window, excision:
Metastatic carcinoma in three of three lymph nodes (3/3).
- H. Lymph nodes, lower paratracheal, excision:
Lymph nodes, four, free of tumor.

AJCC Staging: pT2, pN2, MX

The examination of this case material and the preparation of this report were performed by the staff pathologist.

Electronically Signed

, [Redacted]

Signing Location:

Intraoperative Consult Diagnosis:

- FSE1: Left upper lobe, bronchial resection margin:
Bronchus with no tumor seen.
- FSE2: Left upper lobe, tumor relative to chest wall margin:
Chest wall margin with no tumor seen.
- F/S TAT: 20 mins.

[page 2 of 4]
Gross Description:

The specimen is received in eight parts each labeled with the patient name
" ."

Part A received in formalin labeled "anterior lymph node," and consists of a single probable lymph node received with some associated fat that has a greatest dimension of 1.9 cm. The lymph node is bisected and entirely submitted in cassette A.

Part B received in formalin labeled "inferior pulmonary ligament lymph node," and consists of a portion of irregular, ragged, gray-yellow, lobulated fat that has dimensions of 3.2 x 2.8 x 0.6 cm. The fat contains six probable lymph nodes that range from 0.2 to 1.6 cm in greatest dimension. Lymph nodes are entirely submitted as labeled:

- B1 five lymph nodes submitted in toto;
- B2 one bisected lymph node.

Part C received in formalin labeled "hilar lymph node," and consists of a single probable lymph node received with some associated fat that has a greatest dimension of 1.6 cm. The lymph node is bisected and entirely submitted in cassette C.

Part D received in formalin labeled "tracheobronchial lymph node," and consists of five probable lymph nodes that range from 0.3 to 1.6 cm in greatest dimension. The lymph nodes are entirely submitted as labeled:

- D1 two lymph nodes submitted in toto;
- D2 one lymph node submitted in toto;
- D3 one bisected lymph node;
- D4 one bisected lymph node.

Part E received fresh for intraoperative consultation labeled "left upper lobe," and consists of a left upper lung lobe that has a weight of 491 g and dimensions of 18.2 x 10.6 x 8.5 cm. There is an attached portion of chest wall that is comprised of a single rib with some associated soft tissue that has dimensions of 7.8 x 4.2 x 2.6 cm. This chest wall is only loosely attached to this specimen. The hilar structures are identified with the bronchus opened and the vessels stapled. There are a few extra parenchymal peribronchial lymph nodes present. There is a staple line that radiates superiorly from the hilum that has a length of 8.9 cm. The pleura is gray-purple, smooth and glistening to shaggy with focal cautery effect where the chest wall is adherent to the lung lobe. The specimen is serially sectioned to reveal a red-brown spongy lung parenchyma that is 75% replaced by a gray-yellow to red-brown, focally granular, markedly degenerated and roughly spherical mass that has dimensions of 10.2 x 8.4 x 7.2 cm. This mass extends to within 1.8 cm of the bronchial margin. This mass extends to within 0.2 cm of the inked parenchymal margin. This mass extends to the pleura at the site of the adherent chest wall. This mass grossly appears to invade through the pleura and into the chest wall. This mass extends to within 0.2 cm of the rib and to within 1.2 cm of the anterior chest wall margin. The lung parenchyma distal to the mass is markedly consolidated. There are no additional lesions identified. Representative sections have been submitted for frozen section diagnosis FSE1 and FSE2 with the residue resubmitted for permanent sections in cassettes E1 and E2 respectively.

[page 3 of 4]
Additional representative sections are submitted as labeled:

- E3 anterior rib margin en face after decalcification;
- E4 posterior rib margin en face after decalcification;
- E5 mass to rib and anterior soft tissue margin after decalcification;
- E6 vascular margins en face;
- E7-11 mass to include inked, stapled parenchymal margin in cassettes E7-E8 and pleura at the site of adherent chest wall in cassettes E9 and E10;
- E12 consolidated lung parenchyma distal to mass;
- E13 normal most lung parenchyma;
- E14 two lymph nodes submitted in toto;
- E15 one bisected lymph node.

Part F received in formalin labeled "subcarinal lymph node," and consists of two portions of irregular, ragged, gray-yellow, lobulated fat that have dimensions of 2.2 x 2.0 x 0.8 cm and 2.3 x 2.0 x 0.6 cm. The fat contains eight probable lymph nodes that range from 0.4 to 1.7 cm in greatest dimension. The lymph nodes are submitted in toto in cassettes F1 and F2.

Part G received in formalin labeled "AP window," and consists of three probable lymph nodes that have greatest dimensions of 0.7, 1.3 and 1.4 cm which are submitted in toto in cassette G.

Part H received in formalin labeled "lower paratracheal," and consists of four probable lymph nodes received with some associated fat that have greatest dimensions of 0.4, 0.5, and 1.0 cm which are submitted in toto in cassette H.

Please note: all cassettes are labeled with the case number .

Microscopic Description:

The final diagnosis of each specimen incorporates the microscopic examination findings.

Addendum Report

Date Ordered:

Date Complete:

Date Reported:

Addendum Diagnosis

Sections of the previously decalcified ribs and soft tissues (specimen E) demonstrate a focus of invasive carcinoma involving the posterior rib margin (block E4).

***Electronically Signed ***

Date Ordered:

Date Complete:

Date Reported:

Results-Comments

At the request of Dr. , a representative portion of this case was sent to Molecular Pathology for KRAS mutation analysis. This addendum is

[page 4 of 4]
created to report those findings.

Cerner accession number:

Body site: Left lung, left upper lobe

Specimen type: Paraffin embedded tissue

Surgical Pathology Block number: ,

RESULTS: No KRAS mutations were detected (Wild Type KRAS) at codon 12 of the KRAS gene in the provided specimen. The codon 13 mutations could not be analyzed.

INTERPRETATION: No KRAS mutations were identified at codon 12 of the KRAS gene in the provided specimen. The codon 13 mutations could not be analyzed.

METHOD/ASSAY LIMITATIONS: Tissue sections are reviewed by a pathologist before processing. DNA is isolated and the exon 2 of the KRAS gene is amplified by PCR. PCR products are subjected to Shifted Termination Assay (STA-TrimGen) technology to detect mutations at codons 12 and 13. STA products are analyzed by capillary gel electrophoresis and fluorescence detection. This assay is validated for the detection of mutations in codons 12 and 13 of the KRAS gene. Mutations in other codons of KRAS are not evaluated. False positive or negative results may occur for reasons that include genetic variants or somatic heterogeneity of the tissue sample analyzed. Mutations present in a low percentage of cells may not be detected. Results should be interpreted in conjunction with clinical and other laboratory information findings for the most accurate interpretation.

Taken: [REDACTED]

Source: NCI Genomic Data Commons file ec324506-20cb-442c-9ef1-2e6889e0e665 (TCGA-91-6848.A790E051-B741-4913-AFF6-5A48C9E8E8CD.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).